Somatic mutation profile of tumor specimen MP2PRT-PAUCLU-TBP1-A (aliquot MP2PRT-PAUCLU-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUCLU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,228 days).
Specimen MP2PRT-PAUCLU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) feb25e37-5836-4ae4-b22d-f12b2820a4eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCLU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCLU-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94dd22cc-c665-40a0-80c5-d2efb9988051

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.3320G>A p.R1107H | Missense Mutation (SNP) | VAF 114/422 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs200531128, COSV57001217; called by muse, mutect2, varscan2
- FAM133A | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.02); catalogued as rs199711405, COSV59074132; called by muse, mutect2, varscan2
- FER1L5 | c.2075C>T p.P692L (on ENST00000623019; = p.P697L on NM_001293083.2) | Missense Mutation (SNP) | VAF 117/391 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448705291; called by muse, mutect2, varscan2
- POU5F1B | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 204/668 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.533); catalogued as COSV66966802; called by muse, mutect2, varscan2
- SLCO1C1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV56870727; called by muse, mutect2, varscan2
- CREBBP | c.5423G>T p.C1808F | Missense Mutation (SNP) | VAF 144/484 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DRD2 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINB4 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWCE | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 29/486 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2
- ZBTB38 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- KCNQ5 | c.2055G>A p.S685= | Silent (SNP) | VAF 116/570 reads (20%) | catalogued as rs1298720865, COSV100572909, COSV59652513; called by muse, mutect2, varscan2
- PKD1L2 | n.747G>A | RNA (SNP) | VAF 49/161 reads (30%) | catalogued as rs762345342; called by muse, mutect2, varscan2
